Somatic mutation profile of cancer-model specimen HCM-CSHL-0618-C18-85M (3D Organoid, passage 5; aliquot HCM-CSHL-0618-C18-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0618-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 84.9 years (31,013 days).
Specimen HCM-CSHL-0618-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7e6678f-600d-40a2-865c-6b557e1ec9ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0618-C18-11A (Solid Tissue Normal), aliquot HCM-CSHL-0618-C18-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/635921d7-cd04-42f6-b452-fd0dda48d042

The open-access MAF lists 133 somatic variants for this specimen: 95 protein-altering or splice-affecting, 29 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 87, Silent 29, RNA 4, Nonsense Mutation 3, Frame Shift Del 3, 5'Flank 2, Intron 1, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 178/396 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1610A>T p.D537V | Missense Mutation (SNP) | VAF 277/277 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61684111, COSV61685387, COSV61697211; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 216/216 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.670C>T p.R224W | Missense Mutation (SNP) | VAF 102/324 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs144784477, COSV100711660; called by muse, mutect2, varscan2
- AIMP2 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 188/422 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762651435; called by muse, mutect2, varscan2
- ALDH1A2 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 299/299 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs137957671; called by muse, mutect2, varscan2
- APC | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 269/453 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1402950946; ClinVar: uncertain significance; called by muse, varscan2
- APC | c.4717G>T p.E1573* | Nonsense Mutation (SNP) | VAF 222/363 reads (61%) | catalogued as CM053766, COSV104439189, COSV57323709, COSV57324336, COSV57334217; called by muse, mutect2, varscan2
- ASCL2 | c.148_166del p.A50Mfs*8 | Frame Shift Del (DEL) | VAF 341/590 reads (58%) | catalogued as rs778974931; called by mutect2, varscan2
- BCL11A | c.1627G>A p.E543K (on ENST00000335712 / NM_001365609.1; = p.E577K on NM_018014.4) | Missense Mutation (SNP) | VAF 424/878 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0.122); catalogued as COSV100184567; called by muse, varscan2
- CENPN | c.818C>T p.T273M | Missense Mutation (SNP) | VAF 157/335 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234248777, COSV59904511; called by muse, mutect2, varscan2
- CFAP54 | c.4369T>A p.L1457M | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.98); catalogued as COSV61571635; called by muse, mutect2, varscan2
- CHST5 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 290/594 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1421909496; called by muse, mutect2, varscan2
- CPEB1 | c.1028G>A p.R343Q (on ENST00000617958; = p.R283Q on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/296 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.482); catalogued as COSV55621849; called by muse, mutect2, varscan2
- CRHR2 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 194/447 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756036342; called by muse, mutect2, varscan2
- CROCC2 | c.2558G>A p.R853Q | Missense Mutation (SNP) | VAF 370/727 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753481966; called by muse, mutect2, varscan2
- CSMD1 | c.2564G>A p.R855H (on ENST00000520002; = p.R854H on NM_033225.6) | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as rs376486567; called by muse, mutect2
- CTNNA3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 267/577 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139378888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCHS1 | c.689G>A p.G230D | Missense Mutation (SNP) | VAF 179/537 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1172174294; called by muse, mutect2, varscan2
- DLG2 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as rs1326969221; called by muse, mutect2, varscan2
- EEF2 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 126/478 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58578932; called by muse, mutect2, varscan2
- ERC2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 252/377 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs758640784, COSV99884332; called by muse, mutect2, varscan2
- FAM47C | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 435/459 reads (95%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs1271779756; called by muse, mutect2, varscan2
- GPR119 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 614/614 reads (100%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as rs140173805, COSV52275676; called by muse, mutect2, varscan2
- HDAC9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 211/443 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1400537160, COSV67769993; called by muse, mutect2, varscan2
- HOXB3 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 154/427 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV57488141; called by muse, mutect2, varscan2
- HVCN1 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 46/640 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs773321967; called by muse, mutect2
- LAMB4 | c.4289G>C p.R1430P | Missense Mutation (SNP) | VAF 239/465 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52732914; called by muse, mutect2, varscan2
- LONRF3 | c.200G>A p.S67N | Missense Mutation (SNP) | VAF 739/740 reads (100%) | SIFT tolerated (0.36); PolyPhen benign (0.092); catalogued as rs1464876632; called by muse, mutect2, varscan2
- MSX1 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 236/439 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765128034; called by muse, varscan2
- MYH7 | c.4807G>A p.A1603T | Missense Mutation (SNP) | VAF 371/584 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs730880809, CM146982, COSV62520693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 229/353 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs756530426, COSV55449131; called by muse, mutect2, varscan2
- OR1A1 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 16/524 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1010793556, COSV58403704; called by muse, mutect2
- PILRA | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 202/847 reads (24%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.988); catalogued as rs753428938, COSV52199660; called by muse, varscan2
- PLPPR5 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 350/352 reads (99%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54174184; called by muse, varscan2
- PSG4 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 237/404 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs769047324, COSV54938968, COSV99737771; called by muse, mutect2, varscan2
- RABGAP1 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 178/322 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171254387; called by muse, mutect2, varscan2
- RET | c.1573C>T p.R525W | Missense Mutation (SNP) | VAF 130/615 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs545625150, CM159816, COSV60701403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOBTB2 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 96/192 reads (50%) | catalogued as rs1346573627; called by muse, mutect2, varscan2
- SCN11A | c.4075G>A p.V1359M | Missense Mutation (SNP) | VAF 76/231 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs777323474, COSV56567930, COSV56568066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN4A | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 122/461 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs753391449; called by muse, mutect2, varscan2
- SPATA48 | c.1055A>G p.Y352C | Missense Mutation (SNP) | VAF 178/427 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299431753; called by muse, mutect2
- SPNS2 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 138/456 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs985236722; called by muse, mutect2, varscan2
- TBC1D3B | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 97/369 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as rs1330136710; called by muse, mutect2, varscan2
- TIGD3 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 121/416 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.069); catalogued as COSV52887896; called by muse, mutect2, varscan2
- TLE2 | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 136/434 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568657687; called by muse, varscan2
- TNC | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs763289734, COSV60785514; called by muse, mutect2, varscan2
- ZNF222 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 117/188 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as rs117318348; called by muse, mutect2, varscan2
- ZNF804A | c.3025G>C p.E1009Q | Missense Mutation (SNP) | VAF 234/426 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100168284; called by muse, varscan2
- AAR2 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 89/436 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- ADA2 | c.1316G>T p.S439I (on ENST00000262607; = p.S198I on NM_177405.3) | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADIPOR1 | c.828G>C p.L276F | Missense Mutation (SNP) | VAF 14/442 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- APC | c.1488_1489dup p.L497Hfs*2 | Frame Shift Ins (INS) | VAF 161/496 reads (32%) | called by mutect2, pindel, varscan2
- ARMC4 | c.1022_1023del p.K341Rfs*16 | Frame Shift Del (DEL) | VAF 58/642 reads (9%) | called by mutect2, pindel
- ASPH | c.1379T>G p.L460R | Missense Mutation (SNP) | VAF 133/501 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN1L | c.705G>C p.R235S | Missense Mutation (SNP) | VAF 50/643 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.283); called by muse, mutect2
- BNIP1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 160/441 reads (36%) | called by muse, mutect2, varscan2
- C10orf71 | c.2954G>C p.C985S | Missense Mutation (SNP) | VAF 286/644 reads (44%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC14 | c.823C>T p.P275S (on ENST00000488653; = p.P227S on NM_022757.5) | Missense Mutation (SNP) | VAF 134/456 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CD86 | c.571G>C p.D191H (on ENST00000330540 / NM_175862.5; = p.D185H on NM_006889.4) | Missense Mutation (SNP) | VAF 252/410 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CDH11 | c.2365A>C p.K789Q | Missense Mutation (SNP) | VAF 89/355 reads (25%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CFAP74 | c.101T>A p.I34N | Missense Mutation (SNP) | VAF 122/228 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.731); called by mutect2, varscan2
- FBXO9 | c.1128_1140del p.Q377Rfs*56 | Frame Shift Del (DEL) | VAF 295/400 reads (74%) | called by mutect2, pindel, varscan2
- FGF8 | c.164G>A p.R55K (on ENST00000344255 / NM_033164.4; = p.R37K on NM_006119.6) | Missense Mutation (SNP) | VAF 41/595 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.21); called by muse, mutect2
- FRMPD2 | c.1801A>G p.K601E | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- HDAC5 | c.524A>T p.E175V | Missense Mutation (SNP) | VAF 251/367 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HTR1B | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 60/464 reads (13%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); called by muse, mutect2
- HYDIN | c.10406C>T p.A3469V | Missense Mutation (SNP) | VAF 180/411 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ICE1 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 27/457 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2
- INMT | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 68/701 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCTD19 | c.273G>T p.L91F | Missense Mutation (SNP) | VAF 203/396 reads (51%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LCP2 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.14890C>A p.P4964T | Missense Mutation (SNP) | VAF 89/325 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- NUSAP1 | c.170G>C p.S57T | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OPRD1 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 372/875 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- OR2M3 | c.625T>G p.F209V | Missense Mutation (SNP) | VAF 215/216 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- OR6C3 | c.233T>A p.F78Y | Missense Mutation (SNP) | VAF 99/500 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- PCM1 | c.5345C>G p.S1782C | Missense Mutation (SNP) | VAF 74/129 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKD1L3 | c.5101A>C p.N1701H | Missense Mutation (SNP) | VAF 185/420 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- PLA2G4F | c.1355G>A p.S452N | Missense Mutation (SNP) | VAF 266/267 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PRLHR | c.1023C>G p.S341R | Missense Mutation (SNP) | VAF 269/563 reads (48%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PTPRB | c.5575C>T p.L1859F | Missense Mutation (SNP) | VAF 239/447 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- PXDN | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 70/323 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- RAD51D | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 150/267 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- SIPA1L2 | c.4105T>G p.Y1369D | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SORCS1 | c.1663G>T p.G555C | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SOX11 | c.94G>A p.V32M | Missense Mutation (SNP) | VAF 18/644 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- STAP1 | c.734C>G p.T245R | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- STXBP5L | c.3020+7G>T | Splice Region (SNP) | VAF 244/395 reads (62%) | called by muse, mutect2, varscan2
- SYCP1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 138/138 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TBC1D26 | c.22T>A p.Y8N | Missense Mutation (SNP) | VAF 216/330 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0); called by mutect2, varscan2
- TMTC3 | c.1961G>C p.R654T | Missense Mutation (SNP) | VAF 75/283 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- TRPS1 | c.3325G>T p.D1109Y (on ENST00000220888 / NM_001330599.2; = p.D1122Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 464/640 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- URB1 | c.3134C>T p.A1045V | Missense Mutation (SNP) | VAF 306/447 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ZSCAN16 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 81/641 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTN4 | c.54G>A p.A18= | Silent (SNP) | VAF 148/479 reads (31%) | called by muse, mutect2, varscan2
- AEBP1 | c.75G>A p.P25= | Silent (SNP) | VAF 328/650 reads (50%) | called by muse, varscan2
- ANKFN1 | c.3414C>T p.S1138= (on ENST00000653862; = p.S991= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 158/497 reads (32%) | catalogued as rs1041991870; called by muse, mutect2, varscan2
- ANKRD10 | c.459G>A p.L153= | Silent (SNP) | VAF 151/479 reads (32%) | called by muse, mutect2, varscan2
- ANKRD55 | c.450G>A p.S150= | Silent (SNP) | VAF 120/356 reads (34%) | catalogued as rs747861739, COSV61946235; called by muse, mutect2
- ARHGAP36 | c.696G>A p.A232= | Silent (SNP) | VAF 30/608 reads (5%) | catalogued as COSV52267284; called by muse, mutect2
- BAZ1B | c.2124A>G p.S708= | Silent (SNP) | VAF 235/469 reads (50%) | called by muse, mutect2, varscan2
- CABLES1 | c.1683G>T p.L561= (on ENST00000256925 / NM_001100619.2; = p.L296= on NM_138375.2) | Silent (SNP) | VAF 166/335 reads (50%) | called by muse, mutect2, varscan2
- CCDC14 | c.822G>T p.L274= (on ENST00000488653; = p.L226= on NM_022757.5) | Silent (SNP) | VAF 133/455 reads (29%) | called by muse, mutect2, varscan2
- CCR7 | c.354G>A p.A118= | Silent (SNP) | VAF 127/331 reads (38%) | catalogued as rs199621619; called by muse, mutect2, varscan2
- COL8A1 | c.1782C>T p.G594= | Silent (SNP) | VAF 283/455 reads (62%) | catalogued as rs377127489; called by muse, mutect2, varscan2
- DMXL1 | c.1272C>G p.A424= | Silent (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- EFS | c.522C>G p.T174= | Silent (SNP) | VAF 197/567 reads (35%) | called by muse, mutect2, varscan2
- IL11 | c.525C>T p.H175= | Silent (SNP) | VAF 433/635 reads (68%) | catalogued as rs544256358; called by muse, mutect2, varscan2
- IRS1 | c.3111C>G p.S1037= | Silent (SNP) | VAF 321/634 reads (51%) | catalogued as COSV59337654; called by muse, mutect2, varscan2
- LGI3 | c.1011C>T p.I337= | Silent (SNP) | VAF 152/297 reads (51%) | catalogued as rs773555136, COSV60443274; called by muse, mutect2, varscan2
- LRRC4B | c.1218C>T p.H406= | Silent (SNP) | VAF 335/502 reads (67%) | catalogued as rs752514581, COSV100975927; called by muse, varscan2
- MSX1 | c.360G>T p.V120= | Silent (SNP) | VAF 253/474 reads (53%) | called by muse, mutect2, varscan2
- NEFH | c.603G>T p.A201= | Silent (SNP) | VAF 82/419 reads (20%) | called by muse, mutect2, varscan2
- NIPAL4 | c.1242C>T p.C414= | Silent (SNP) | VAF 211/528 reads (40%) | catalogued as rs373794632; called by muse, mutect2, varscan2
- NUTM1 | c.834C>A p.I278= | Silent (SNP) | VAF 188/190 reads (99%) | called by muse, mutect2, varscan2
- PCDHA7 | c.2115C>T p.C705= | Silent (SNP) | VAF 26/517 reads (5%) | catalogued as COSV100971055; called by muse, mutect2
- PCDHGB4 | c.1866C>T p.G622= | Silent (SNP) | VAF 190/553 reads (34%) | catalogued as rs751642051, COSV53914791; called by muse, mutect2, varscan2
- PRRT1B | c.474C>T p.A158= | Silent (SNP) | VAF 38/508 reads (7%) | called by muse, mutect2
- RCAN1 | c.81G>C p.G27= | Silent (SNP) | VAF 288/449 reads (64%) | catalogued as rs1018546479; called by muse, mutect2, varscan2
- ROGDI | c.768C>T p.D256= | Silent (SNP) | VAF 231/478 reads (48%) | catalogued as rs753887163; called by muse, mutect2, varscan2
- UBE2O | c.1713C>T p.N571= | Silent (SNP) | VAF 194/332 reads (58%) | catalogued as rs747956830; called by muse, mutect2, varscan2
- UBTD1 | c.432C>T p.S144= | Silent (SNP) | VAF 438/878 reads (50%) | catalogued as rs1210329059; called by muse, mutect2, varscan2
- VEPH1 | c.1392C>T p.D464= | Silent (SNP) | VAF 233/356 reads (65%) | catalogued as rs113924904; called by muse, mutect2, varscan2
- CCDC169 | chr13:36227157 G>T | 3'Flank (SNP) | VAF 606/741 reads (82%) | called by muse, mutect2
- FSIP2 | chr2:185738689 G>A | 5'Flank (SNP) | VAF 326/633 reads (52%) | called by muse, mutect2, varscan2
- H2BP2 | n.1061+444C>T | Intron (SNP) | VAF 174/215 reads (81%) | catalogued as rs1441260230; called by muse, mutect2, varscan2
- MYCBP2 | c.*59G>A | 3'UTR (SNP) | VAF 126/756 reads (17%) | catalogued as rs531263957; called by muse, mutect2, varscan2
- NPAP1L | n.816C>T | RNA (SNP) | VAF 196/366 reads (54%) | catalogued as rs1294297918, COSV73747282; called by muse, mutect2, varscan2
- NPAP1L | n.528C>T | RNA (SNP) | VAF 48/366 reads (13%) | called by muse, varscan2
- NPAP1L | n.527C>T | RNA (SNP) | VAF 50/364 reads (14%) | catalogued as COSV73747612; called by muse, varscan2
- NPAP1L | n.526C>T | RNA (SNP) | VAF 50/370 reads (14%) | called by muse, varscan2
- Z99774.2 | chr22:26671822 C>A | 5'Flank (SNP) | VAF 194/195 reads (99%) | called by muse, mutect2, varscan2
